Somatic mutation profile of tumor specimen TCGA-XD-AAUG-01A (aliquot TCGA-XD-AAUG-01A-61D-A40W-08) from TCGA case TCGA-XD-AAUG, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 66.5 years (24,291 days).
Specimen TCGA-XD-AAUG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ece2d8c2-ac72-43c8-82d6-d1f997701fb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XD-AAUG-10A (Blood Derived Normal), aliquot TCGA-XD-AAUG-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fa9075d-b80e-43cb-b8b5-82fd621c343a

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP5MF-PTCD1 | c.67T>A p.W23R | Missense Mutation (SNP) | VAF 66/1272 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99461802; called by muse, mutect2
- BNC2 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 13/360 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as rs945086064, COSV101033726; called by muse, mutect2
- C4A | c.3532T>C p.F1178L | Missense Mutation (SNP) | VAF 44/735 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.681); catalogued as COSV101418347; called by muse, mutect2
- COL1A1 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 45/720 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99867642; called by muse, mutect2
- FOXS1 | c.650C>A p.A217E | Missense Mutation (SNP) | VAF 21/314 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV99640018; called by muse, mutect2
- MCCC1 | c.2110C>T p.Q704* | Nonsense Mutation (SNP) | VAF 66/796 reads (8%) | catalogued as COSV55606687; called by muse, mutect2
- ME2 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 22/367 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100360841; called by muse, mutect2
- OR5P3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 34/451 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as rs117218570, COSV60429066, COSV60429677; called by muse, mutect2
- PLEKHA5 | c.2659G>A p.V887M | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV100164364; called by muse, mutect2
- POTEF | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 34/698 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as COSV100665074; called by muse, mutect2
- PRKCD | c.1798C>A p.H600N | Missense Mutation (SNP) | VAF 47/1350 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV100387960; called by muse, mutect2
- TBC1D8 | c.806A>T p.E269V | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV100964537; called by muse, mutect2
- DCAF12L1 | c.259C>T p.L87= | Silent (SNP) | VAF 16/442 reads (4%) | catalogued as COSV100948365; called by muse, mutect2
- ENTPD4 | c.1656C>T p.H552= | Silent (SNP) | VAF 10/276 reads (4%) | catalogued as COSV100652699; called by muse, mutect2
- FPR1 | c.414C>T p.T138= | Silent (SNP) | VAF 23/348 reads (7%) | catalogued as rs151277630; called by muse, mutect2
- TUBAL3 | c.54C>T p.D18= | Silent (SNP) | VAF 16/424 reads (4%) | catalogued as rs148158899; called by muse, mutect2
